Gene-level copy-number profile of tumor specimen TCGA-AC-A5EI-01A from TCGA case TCGA-AC-A5EI, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Phyllodes tumor, malignant; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 88.6 years (32,375 days).
Specimen TCGA-AC-A5EI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.92324d49-edbe-410b-9613-47089246d8a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A5EI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d020a266-f9e9-4099-8615-fc4cf3b82e2d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 2: 2,420; copy number 3: 1,141; copy number 4: 37,710; copy number 5: 2,787; copy number 6: 5,431; copy number 7: 2,981; copy number 8: 4,281; copy number 10: 3,014.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A5EI-01A-11D-A27O-01): tumor purity 0.5, ploidy 2.49, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,709,016–141,938,547, 11 genes: TPT1P3, AC112771.1, RNF7, AC112504.2, GRK7, AC112504.3, HMGN2P25, ATP1B3, RNU6-509P, ATP1B3-AS1, AC112504.1.
- chr9:21,966,929–23,672,387, 16 genes (within-gene range 0–4): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,014 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–159,233,377, 3,014 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
